Somatic mutation profile of tumor specimen TCGA-93-A4JO-01A (aliquot TCGA-93-A4JO-01A-21D-A24P-08) from TCGA case TCGA-93-A4JO, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.9 years (25,898 days).
Specimen TCGA-93-A4JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f67a0e57-d1da-429d-a65a-7ddf226727ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-A4JO-10A (Blood Derived Normal), aliquot TCGA-93-A4JO-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9b12d1-3446-400a-ba0e-4491167c75a9

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Nonsense Mutation 4, Splice Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ACCSL | c.1026G>C p.M342I | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV101122207; called by muse, mutect2
- CFAP54 | c.5401A>T p.K1801* | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | catalogued as COSV100733237; called by muse, mutect2, varscan2
- CHML | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV100087500; called by muse, mutect2
- CSMD1 | c.6311A>G p.Y2104C (on ENST00000520002; = p.Y2103C on NM_033225.6) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100149344; called by muse, mutect2, varscan2
- CXCL2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | catalogued as COSV56021646, COSV99933208; called by muse, mutect2
- DCSTAMP | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99886629; called by muse, mutect2
- DGCR8 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100708019; called by muse, mutect2
- DOP1A | c.4318C>G p.P1440A | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.192); catalogued as COSV99382175; called by muse, mutect2
- EMC8 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99495717; called by muse, mutect2
- EREG | c.416A>C p.Y139S | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99791752; called by muse, mutect2
- FAM71F1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs545990920, COSV100171036; called by muse, mutect2, varscan2
- FNDC3B | c.2242G>C p.D748H | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100394321; called by muse, mutect2
- GBP1 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100976274; called by muse, mutect2
- GLS2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358382; called by muse, mutect2
- HNRNPK | c.157-1G>C p.X53_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100366310; called by muse, mutect2
- HTR3E | c.884T>C p.M295T (on ENST00000415389 / NM_001256613.1; = p.M310T on NM_182589.2) | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100094220; called by muse, mutect2
- IGLV2-18 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs1427310277; called by muse, mutect2
- LAMC3 | c.4186A>T p.K1396* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100736005; called by muse, mutect2, varscan2
- LY75 | c.3430C>A p.P1144T | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV99716576; called by muse, mutect2, varscan2
- MAP7D3 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV100286415, COSV60170352; called by muse, mutect2, varscan2
- MMP7 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99497084; called by muse, mutect2, varscan2
- MPHOSPH8 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV100825148; called by muse, mutect2
- MS4A10 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV100382329; called by muse, mutect2
- NDUFS2 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV63487445; called by muse, mutect2
- NFATC3 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV100285325; called by muse, mutect2
- PRX | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV99397771; called by muse, mutect2
- RAPGEF2 | c.280A>T p.I94F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.598); catalogued as COSV100031291; called by muse, mutect2, varscan2
- SSH3 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100354610, COSV100354615; called by muse, mutect2, varscan2
- TLR9 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs777140542, COSV100645673; called by muse, mutect2, varscan2
- TNRC6A | c.2374T>C p.W792R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100170139; called by muse, mutect2, varscan2
- TRIM58 | c.499A>C p.K167Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100825140; called by muse, mutect2
- USP54 | c.3998G>T p.G1333V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100357433; called by muse, mutect2, varscan2
- ZNF280C | c.1307A>T p.H436L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100921244; called by muse, mutect2, varscan2
- ZNF443 | c.481A>T p.R161W | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100042190; called by muse, mutect2
- ACACA | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2
- CHMP6 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.281); called by muse, mutect2
- HOXA6 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- OR51G2 | c.396C>A p.C132* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- RMC1 | c.965del p.P322Lfs*4 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- ATP8A1 | c.1998A>G p.Q666= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV100046454; called by muse, mutect2, varscan2
- DEFB124 | c.108T>G p.T36= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV58343742; called by muse, mutect2, varscan2
- ELAPOR1 | c.2922C>T p.I974= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100884445; called by muse, mutect2
- GPM6A | c.672A>T p.A224= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- IL12B | c.510C>T p.C170= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs771036480, COSV51454347; called by muse, mutect2, varscan2
- KIR3DL2 | c.228C>T p.F76= | Silent (SNP) | VAF 34/238 reads (14%) | catalogued as COSV99552134; called by muse, mutect2, varscan2
- RGS9 | c.1530C>G p.P510= | Silent (SNP) | VAF 14/233 reads (6%) | catalogued as COSV99287564; called by muse, mutect2
- ZNF491 | c.315T>C p.C105= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV100021927; called by muse, mutect2, varscan2
- TBX2 | chr17:61412441 G>T | 3'Flank (SNP) | VAF 9/26 reads (35%) | catalogued as rs541405293; called by muse, mutect2, varscan2
